Gene-level copy-number profile of tumor specimen TCGA-VQ-A928-01A from TCGA case TCGA-VQ-A928, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 49.4 years (18,058 days).
Specimen TCGA-VQ-A928-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.d6ab2013-fa3b-4877-823f-2265b6061675.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A928-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bc748523-4271-4353-85de-eb416bf6a52c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 3,602; copy number 2: 49,478; copy number 3: 6,578; copy number 4: 68; copy number 5: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A928-01A-11D-A40Z-01): tumor purity 0.56, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:159,318,979–159,616,569, 1 gene (within-gene range 0–2): BAZ2B.
- chr2:159,462,417–159,771,027, 6 genes: CAPZA1P2, Y_RNA, AC009506.1, AC009961.1, RPS3AP13, MARCHF7.
- chr3:52,287,089–52,685,917, 16 genes (within-gene range 0–2): GLYCTK, GLYCTK-AS1, MIR135A1, DNAH1, PPP2R5CP, BAP1, PHF7, SEMA3G, TNNC1, NISCH, STAB1, NT5DC2, SMIM4, PBRM1, RNU6-856P, RNU6ATAC16P.
- chr7:157,539,056–158,587,823, 1 gene (within-gene range 0–1): PTPRN2.
- chr7:157,739,010–158,031,128, 5 genes: AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1.
- chr12:1,529,891–1,647,212, 2 genes (within-gene range 0–1): WNT5B, FBXL14.
- chr12:124,324,415–124,567,589, 1 gene (within-gene range 0–2): NCOR2.
- chr12:124,383,381–124,638,444, 11 genes: AC073916.1, AC073592.1, AC073592.7, AC073592.3, AC073592.9, AC073592.5, AC073592.6, AC073592.8, AC073592.2, AC073592.10, AC073592.4.
- chr13:72,727,749–73,016,461, 4 genes (within-gene range 0–3): BORA, DIS3, PIBF1, RNU6-79P.
- chr15:90,839,641–90,954,093, 8 genes (within-gene range 0–2): AC124248.1, RN7SL363P, FURIN, FES, MAN2A2, AC068831.3, HDDC3, UNC45A.
- chr16:12,560,756–12,611,044, 1 gene (within-gene range 0–1): AC010333.2.
- chr16:78,793,584–79,017,429, 8 genes: AC009141.1, RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4.
- chr16:81,445,170–81,711,762, 9 genes (within-gene range 0–1): CMIP, AC092139.1, PPIAP51, AC092139.2, MIR7854, MIR6504, AC092135.2, AC092135.1, AC092135.3.
- chr16:89,737,549–89,816,657, 1 gene (within-gene range 0–1): FANCA.
- chr21:34,836,286–34,884,882, 1 gene (within-gene range 0–1): AP000331.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:86,026,146–86,132,851, 3 genes, copy number 5 (within-gene range 3–5): GOLM1, AL161447.2, AL161447.1.

Autosomal genes at a single copy (total copy number 1): 1,274. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
